Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3450, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3450-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right renal mass
Source of Specimen(s):
right Kidney, radical nephrectomy for tumor

Gross Description:
Received in one part.
Source of Tissue: 1. Labeled # 1, "right kidney"

Gross Description: Received fresh in a container labeled , right kidney". It consists of a 360 gram radical nephrectomy specimen consisting of kidney measuring 10.0 x 6.0 x 6.0 cm and perinephric fat ranging from 0.3 up to 5.0 cm. Dissection through the fat discloses no obvious lesions, masses or nodal tissue however, there is a firm bulging mass at the hilum protruding from the kidney. Also at the hilum there is an 8.0 x 0.3 cm segment of ureter. The ureter is opened and grossly free of lesions or masses. The kidney is sectioned disclosing a 4.0 x 3.5 x 2.7 cm soft orange mass having a moderate amount of hemorrhage and possible degenerative changes. It is difficult to tell whether the tumor is through the capsule however, the lesion does push well into the hilum and renal pelvis. The calyceal system and vessels are uninvolved by lesion. Elsewhere, two small simple cysts [cortical cysts] containing clear thin fluid are found measuring 0.9 and 1.0 cm. Both cysts are lateral and superiorly in the kidney. Elsewhere, there is some possible scarring at the remaining parenchyma with well-delineated cortical-medullary junctions. Representative sections are submitted in 1A-H.

Designation of Sections: 1A- vascular and ureter margins, 1B- tumor in relationship to ureter at hilum, 1C- tumor in relationship to normal adjacent parenchyma, 1D-1E- tumor in relationship to overlying capsule, 1F- uninvolved kidney with cyst, 1G- uninvolved kidney, 1H- fat at hilum

Final Diagnosis:

Right kidney:

Renal cell carcinoma, clear cell (conventional) type, Fuhrman nuclear grade II/IV.

- The 4.0 cm carcinoma is confined to renal parenchyma.
- Angiolymphatic invasion is not identified.
- Surgical resection margins are free of carcinoma.

Tubular/papillary adenoma.

Renal cortical cysts.

Benign arterio-arteriolar nephrosclerosis.

pTNM: T1a Nx Mx

Source: NCI Genomic Data Commons file 3d8e802c-6b6d-45e8-83a8-cf74f784b404 (TCGA-AK-3450.FF1F991C-B72A-47B0-964B-6A348B4BDB52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).